Gene-level copy-number profile of tumor specimen TCGA-25-1878-01A from TCGA case TCGA-25-1878, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.3 years (22,035 days).
Specimen TCGA-25-1878-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d0c4dcaa-e4f3-453a-bff5-accc4edaf5dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1878-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/315f5f77-9e60-45af-90e4-69f917306656

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,858; copy number 2: 11,110; copy number 3: 25,366; copy number 4: 12,162; copy number 5: 4,304; copy number 6: 1,041; copy number 7: 1,461; copy number 9: 126; copy number 10: 1,346; copy number 25: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1878-01): tumor purity 0.56, ploidy 3.62, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:75,642,494–75,656,016, 1 gene: AC090338.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,972 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–155,331,114, 552 genes, copy number 7–9 (broad region; genes not listed).
- chr1:155,346,350–155,396,978, 3 genes, copy number 7: MIR555, RNU6-106P, ASH1L-IT1.
- chr1:218,881,600–248,919,946, 719 genes, copy number 9–10 (broad region; genes not listed).
- chr2:53,470,447–54,680,045, 22 genes, copy number 7: AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1.
- chr2:54,747,103–54,801,540, 2 genes, copy number 7: EML6-AS1, AC104781.1.
- chr3:167,239,843–198,222,513, 613 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr5:3,357,264–54,737,057, 683 genes, copy number 10–25 (within-gene range 4–25) (broad region; genes not listed).
- chr6:167,607–23,649,774, 378 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,026. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
